Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2M7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2M7-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:

Male

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTOPATHOLOGY REQUEST DETAILS

CLINICAL NOTES

Right axillary dissection for metastatic melanoma

SPECIMEN INFORMATION

Axillary contents - hist.

MACROSCOPIC DESCRIPTION

Two specimens were received.

I. "Axillary contents (R) long tie marks apex". The specimen consists of a skin ellipse 90 x 10mm and underlying fibrofatty mass 150 x 130 x 30mm. There is a long stitch indicating the apex. The excision margin was inked blue. No macroscopic lesion seen on the skin surface. There is a large lymph node 30 x 15 x 15mm at the apical tie.

- A. Two ends of the skin ellipse.
- B. Section across surgical tie.
- C-E. Next three slices of the same lymph node.
- F. Next slice ? 1 lymph node.

On sectioning there is a large mass (? lymph node) 20 x 20 x 15mm.

G&H. Large mass.

- J. 1 lymph node.
- K. 2 lymph nodes.
- L. 2 lymph nodes.
- M. 3 lymph nodes.
- N. 2 lymph nodes.
- O. 2 lymph nodes.
- P. 3 lymph nodes.
- Q. 2 lymph nodes.
- R. 1 lymph node.

II. "Tumour right axilla (nodal tissue)". A circumscribed mass 15 x 15mm. The surgical margins were inked blue. Embedded in one block.

MICROSCOPIC REPORT

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

I. "Axillary contents (R) long tie marks apex". About 60% of the apical lymph node (B-E) is replaced by malignant melanoma. There is focal extranodal spread. There are 14 out of the remaining 20 lymph node with metastatic malignant melanoma and 9 of these show extranodal extension. The remaining 6 lymph node show no evidence of malignancy. The overlying skin shows no evidence of malignancy.

II. "Tumour (R) axilla (nodal tissue)". Sections show one lymph node with metastatic malignant melanoma and extranodal tumour extension.

Immunoperoxidase stains:

The tumour is positive for S100 but no HMB45. The results confirm the diagnosis of malignant melanoma.

Electronic signature

Verified by:

COMMENT

- I. "Axillary contents (R) long tie marks tie". Metastatic malignant melanoma, in 15/21 lymph node.
- II. "Tumour (R) axilla (nodal tissue)". Metastatic malignant melanoma in 1 lymph node.

SUMMARY / KEY WORDS

Lymph node - malignant melanoma, metastatic
Haematopathology resection

Source: NCI Genomic Data Commons file 3a9014b6-4de2-4612-be6f-f40424eda34d (TCGA-EE-A2M7.8CDEC44A-0A01-4598-B165-871290AF0FEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).